Gene-level copy-number profile of tumor specimen ALCH-ADO6-TTP1-A from ALCHEMIST case ALCH-ADO6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.0 years (19,007 days).
Specimen ALCH-ADO6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 514840e8-ee49-49b0-bcfd-694f5bee82cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADO6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/335a9b2f-4e50-4493-9905-718885eaf3ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 4,041; copy number 2: 54,670; copy number 3: 84; copy number 4: 9; copy number 7: 1; copy number 11: 5; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,308,597–1,335,314, 6 genes (within-gene range 0–1): PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3.
- chr1:1,339,650–1,339,708, 1 gene (within-gene range 0–1): MIR6808.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr8:142,750,150–142,778,224, 5 genes: LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1.
- chr15:25,135,642–25,250,940, 47 genes (within-gene range 0–2): PWAR1, SNORD115, DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:74,843,730–74,873,365, 1 gene: SCAMP2.
- chr16:57,759,358–57,760,024, 1 gene (within-gene range 0–2): AC092118.2.
- chr17:83,079,609–83,106,910, 3 genes: METRNL, AC130371.2, AC144831.1.
- chr19:4,639,516–4,655,568, 1 gene (within-gene range 0–2): TNFAIP8L1.
- chr19:19,516,227–19,546,659, 3 genes (within-gene range 0–2): AC011448.1, YJEFN3, CILP2.
- chr20:63,696,652–63,708,025, 2 genes (within-gene range 0–2): TNFRSF6B, ARFRP1.
- chr22:19,783,223–19,854,939, 3 genes (within-gene range 0–2): GNB1L, AC000089.1, RTL10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,968,609–87,973,082, 2 genes, copy number 11: NDUFB4P7, WBP1P2.
- chr8:12,425,614–12,436,343, 1 gene, copy number 7: FAM86B2.
- chr21:44,133,610–44,210,114, 1 gene, copy number 21 (within-gene range 1–21): GATD3A.
- chr21:44,217,014–44,244,993, 3 genes, copy number 11: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 1,228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
